Somatic mutation profile of tumor specimen TCGA-EL-A4JZ-01A (aliquot TCGA-EL-A4JZ-01A-11D-A257-08) from TCGA case TCGA-EL-A4JZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 55.6 years (20,290 days).
Specimen TCGA-EL-A4JZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d115ea2-bbec-4d0b-af74-653c45d8d81b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A4JZ-11A (Solid Tissue Normal), aliquot TCGA-EL-A4JZ-11A-11D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6ebe68af-65e1-4feb-83d4-84e236f85d8b

The open-access MAF lists 13 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent.
By variant classification: Silent 5, Missense Mutation 5, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT2 | c.49G>A p.E17K | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906659, CM118819, COSV60907479; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/64 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- CLIC2 | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 21/64 reads (33%) | catalogued as COSV58935850; called by muse, mutect2, varscan2
- DCLRE1B | c.1014G>A p.W338* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV65812323; called by muse, mutect2, varscan2
- ERAP2 | c.434A>G p.H145R | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.066); catalogued as rs554491944, COSV65939017; called by muse, mutect2, varscan2
- KRTAP5-6 | c.44G>C p.G15A | Missense Mutation (SNP) | VAF 43/146 reads (29%) | PolyPhen probably damaging (0.969); catalogued as COSV66289151; called by muse, mutect2, varscan2
- SORCS3 | c.2626G>A p.E876K | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.883); catalogued as rs762857852, COSV63793888, COSV63794694; called by muse, mutect2, varscan2
- NCAM2 | c.2009del p.N670Ifs*35 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- LRRTM3 | c.690C>T p.S230= | Silent (SNP) | VAF 28/82 reads (34%) | catalogued as COSV63662679; called by muse, mutect2, varscan2
- PREX1 | c.3819G>A p.L1273= | Silent (SNP) | VAF 6/123 reads (5%) | catalogued as COSV64248978; called by muse, mutect2
- TGFB2 | c.1053G>C p.P351= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV65108352; called by mutect2, varscan2
- WRAP53 | c.222T>C p.S74= | Silent (SNP) | VAF 30/91 reads (33%) | catalogued as COSV52817632; called by muse, mutect2, varscan2
- ZNF549 | c.1017A>G p.K339= (on ENST00000376233 / NM_001199295.2; = p.K326= on NM_153263.2) | Silent (SNP) | VAF 22/67 reads (33%) | catalogued as COSV53724182; called by muse, mutect2, varscan2
